Somatic mutation profile of tumor specimen TARGET-20-PASDET-04A (aliquot TARGET-20-PASDET-04A-01D) from TARGET case TARGET-20-PASDET, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.6 years (7,165 days).
Specimen TARGET-20-PASDET-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88bc147c-82c2-4034-94c9-16048e5ca61d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASDET-14A (Bone Marrow Normal), aliquot TARGET-20-PASDET-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10be92ea-bc95-409c-af98-460f4f837456

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 33/70 reads (47%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- WT1 | c.1105_1108dup p.A370Vfs*4 | Frame Shift Ins (INS) | VAF 40/138 reads (29%) | catalogued as COSV60065440; called by mutect2, varscan2
- NFAT5 | c.*7141C>T | 3'UTR (SNP) | VAF 12/316 reads (4%) | catalogued as rs1247092738; called by muse, mutect2
